Somatic mutation profile of tumor specimen TCGA-50-6673-01A (aliquot TCGA-50-6673-01A-11D-1945-08) from TCGA case TCGA-50-6673, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage I; Age at diagnosis: 84.0 years (30,689 days).
Specimen TCGA-50-6673-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c981f20f-e70c-410b-b9a3-e731e1d14e84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-6673-11A (Solid Tissue Normal), aliquot TCGA-50-6673-11A-02D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce45d80b-ae25-4619-9f31-81183ad14a79

The open-access MAF lists 59 somatic variants for this specimen: 47 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 8, Frame Shift Del 4, Nonsense Mutation 2, Frame Shift Ins 2, Intron 2, Splice Region 1, RNA 1, In Frame Ins 1, 3'UTR 1, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2317_2319dup p.H773dup | In Frame Ins (INS) | VAF 106/263 reads (40%) | hotspot (GDC flag); catalogued as rs1554350381, COSV51800933, COSV51820458; ClinVar: uncertain significance; called by pindel, varscan2
- FOXG1 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786205007, CM1210351, COSV57398603; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 31/61 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADIPOQ | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs182223755, COSV57859747; called by muse, mutect2, varscan2
- ANKRD34A | c.979T>G p.S327A | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV60161725; called by muse, mutect2, varscan2
- ARAP1 | c.2914G>A p.V972M (on ENST00000393609 / NM_001040118.2; = p.V727M on NM_015242.4) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1330028999, COSV61993615; called by muse, mutect2, varscan2
- CANX | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV56006033; called by muse, mutect2, varscan2
- CCNB3 | c.4187A>G p.*1396Wext*6 | Nonstop Mutation (SNP) | VAF 4/58 reads (7%) | catalogued as COSV52077754; called by muse, mutect2
- CDH7 | c.1505A>G p.K502R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV59891345; called by muse, mutect2, varscan2
- CHEK2 | c.1304C>T p.A435V (on ENST00000382580 / NM_001005735.2; = p.A392V on NM_007194.4) | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs373073383; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- CPD | c.3288T>G p.D1096E | Missense Mutation (SNP) | VAF 16/275 reads (6%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as COSV56715050; called by muse, mutect2
- CRB1 | c.917G>A p.W306* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | catalogued as COSV66345848; called by muse, mutect2, varscan2
- CYP4F11 | c.594G>T p.M198I | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV56128747; called by muse, mutect2, varscan2
- FAM155B | c.510C>A p.D170E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.114); catalogued as COSV52937174; called by muse, mutect2
- FGF10 | c.279G>C p.E93D | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52937968; called by muse, mutect2, varscan2
- GBF1 | c.562A>G p.M188V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1467300528, COSV64147687; called by muse, mutect2, varscan2
- GGT5 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.956); catalogued as COSV54071512, COSV54071840; called by muse, mutect2
- HSD17B3 | c.836G>A p.S279N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV64557990; called by muse, mutect2, varscan2
- IL1RL1 | c.227C>A p.P76Q | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52118971; called by muse, mutect2, varscan2
- KIF20A | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as rs756187494, COSV67510320; called by muse, mutect2
- MUC4 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV100641651, COSV62201621; called by muse, mutect2, varscan2
- MYO18A | c.410A>G p.K137R | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.115); catalogued as rs1420509879, COSV62871319; called by muse, mutect2, varscan2
- N4BP2 | c.2495C>G p.S832C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); catalogued as COSV54705335; called by muse, mutect2, varscan2
- NUP107 | c.898A>G p.T300A | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1312896554, COSV57496899; called by muse, varscan2
- OR10J3 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV59955270; called by muse, mutect2, varscan2
- OR52N1 | c.830T>A p.I277N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57693832; called by muse, mutect2, varscan2
- PAPPA2 | c.3219C>A p.H1073Q | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV62794556; called by muse, mutect2
- PCDHA5 | c.1297_1298insA p.S433Yfs*167 | Frame Shift Ins (INS) | VAF 35/182 reads (19%) | catalogued as COSV100972478; called by mutect2, pindel, varscan2
- PDE10A | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as rs770788354, COSV63096001; called by muse, mutect2, varscan2
- PHLDB2 | c.3160G>T p.E1054* (on ENST00000393925 / NM_001134439.2; = p.E1011* on NM_145753.2) | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV67314693; called by muse, mutect2, varscan2
- PLEKHG3 | c.2014G>A p.E672K (on ENST00000394691; = p.E728K on NM_001308147.2) | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753226519, COSV55982474, COSV99906385; called by muse, mutect2, varscan2
- PPIG | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.579); catalogued as rs182401677, COSV53645052; called by muse, mutect2, varscan2
- PTCHD1 | c.2521A>G p.I841V | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV65062100; called by muse, mutect2, varscan2
- REEP2 | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs147103044, COSV54734658; called by muse, mutect2, varscan2
- SHCBP1 | c.1718C>G p.T573R | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV57649472; called by muse, mutect2, varscan2
- TACC2 | c.3057A>T p.E1019D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV57766728; called by muse, mutect2, varscan2
- TINAG | c.1041G>T p.R347S | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.38); catalogued as COSV99450427; called by muse, mutect2
- TM4SF1 | c.250T>G p.C84G | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV59525358; called by muse, mutect2
- WDR13 | c.941C>A p.A314D | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.691); catalogued as COSV54332946; called by muse, varscan2
- ZBTB37 | c.1023+7A>G | Splice Region (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100875292; called by muse, mutect2, varscan2
- ABCC4 | c.1851del p.Y617* | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel
- FAM184A | c.1917dup p.K640* | Frame Shift Ins (INS) | VAF 21/71 reads (30%) | called by mutect2, pindel, varscan2
- PLPP4 | c.375_377del p.M126del | In Frame Del (DEL) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- SLC7A5 | c.1181del p.F394Sfs*22 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- SRSF10 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBX5 | c.1511_1512del p.S504Cfs*14 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by pindel, varscan2
- TTC3 | c.4714_4723del p.S1572Rfs*43 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, varscan2
- ACKR4 | c.729C>T p.L243= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs771511165, COSV51443286; called by mutect2, varscan2
- ADAMTS2 | c.3492C>T p.P1164= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as COSV52386697; called by muse, mutect2, varscan2
- CAMTA1 | c.621G>A p.A207= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as rs370264033; called by muse, mutect2, varscan2
- DHX37 | c.3243G>C p.R1081= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1477856022, COSV58137631; called by muse, mutect2, varscan2
- MUC4 | c.27C>G p.V9= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV100641655; called by muse, mutect2, varscan2
- TRIM41 | c.714C>T p.C238= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs768419618, COSV59321479; called by muse, mutect2, varscan2
- VPS16 | c.2121T>G p.G707= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV66797622; called by muse, mutect2, varscan2
- ZEB2 | c.3591G>A p.G1197= | Silent (SNP) | VAF 64/340 reads (19%) | catalogued as rs1445900102, COSV57962883; called by muse, mutect2, varscan2
- AL590867.2 | n.90C>T | RNA (SNP) | VAF 54/180 reads (30%) | catalogued as rs754507115; called by muse, mutect2, varscan2
- COL6A2 | c.2461+2696C>T | Intron (SNP) | VAF 31/194 reads (16%) | catalogued as rs534856775, COSV56008091; called by muse, mutect2, varscan2
- SKAP1 | c.978+5966G>A | Intron (SNP) | VAF 6/38 reads (16%) | catalogued as rs764824939, COSV61150266; called by mutect2, varscan2
- SORCS1 | c.*167A>G | 3'UTR (SNP) | VAF 26/89 reads (29%) | catalogued as rs1477628255, COSV53845312; called by muse, varscan2
